Somatic mutation profile of tumor specimen TCGA-WB-A80O-01A (aliquot TCGA-WB-A80O-01A-11D-A35I-08) from TCGA case TCGA-WB-A80O, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 83.7 years (30,555 days).
Specimen TCGA-WB-A80O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6551af3-b646-43ae-b9fc-1082160b6036.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80O-10A (Blood Derived Normal), aliquot TCGA-WB-A80O-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47648fb6-1809-4cb6-8715-84feb023e382

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 40/79 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRT6C | c.1355T>C p.M452T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs1292627189; called by muse, mutect2, varscan2
- NDN | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.188); catalogued as rs201121842; called by muse, mutect2, varscan2
- TCHHL1 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs756910240; called by muse, mutect2
- P3H2 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- SCP2 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, mutect2
- TNK2 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); called by muse, mutect2
- PIK3CA | c.688C>A p.R230= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV55905040, COSV55908759; called by muse, mutect2, varscan2
- SLC35G2 | c.156T>C p.N52= | Silent (SNP) | VAF 53/159 reads (33%) | called by muse, mutect2
